Somatic mutation profile of tumor specimen ALCH-B37V-TTP1-A (aliquot ALCH-B37V-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B37V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.9 years (17,858 days).
Specimen ALCH-B37V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6bfb3c1-74cc-4dff-b350-d6e2c4302d76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37V-NB1-A (Blood Derived Normal), aliquot ALCH-B37V-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e12ceadd-2650-4ca4-98e8-a3f0ba696e12

The open-access MAF lists 4 somatic variants for this specimen: 4 silent.
By variant classification: Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC093323.1 | c.273A>G p.E91= | Silent (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- BRWD3 | c.5125A>C p.R1709= | Silent (SNP) | VAF 12/269 reads (4%) | called by muse, mutect2
- DDB1 | c.3306C>G p.R1102= | Silent (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- SBK1 | c.1158G>A p.P386= | Silent (SNP) | VAF 118/420 reads (28%) | catalogued as rs1156408147; called by muse, mutect2, varscan2
